Somatic mutation profile of tumor specimen TCGA-55-8615-01A (aliquot TCGA-55-8615-01A-11D-2393-08) from TCGA case TCGA-55-8615, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 67.9 years (24,786 days).
Specimen TCGA-55-8615-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1c198ca7-c422-4ea5-928c-77f28fe14eeb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-8615-10A (Blood Derived Normal), aliquot TCGA-55-8615-10A-01D-2393-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/085615ac-a63a-4092-81c6-7763dfc548a0

The open-access MAF lists 132 somatic variants for this specimen: 87 protein-altering or splice-affecting, 40 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 40, Nonsense Mutation 6, Frame Shift Del 3, In Frame Del 2, Splice Site 2, RNA 2, 3'UTR 1, 3'Flank 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 18/43 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- STK11 | c.658C>T p.Q220* | Nonsense Mutation (SNP) | VAF 22/30 reads (73%) | hotspot (GDC flag); catalogued as rs1131690940, CM991157, COSV58820792; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC6 | c.826G>T p.G276C | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.438); catalogued as COSV52743291, COSV99229092; called by muse, mutect2
- ACIN1 | c.128C>A p.P43Q | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.78); catalogued as COSV99399840; called by muse, mutect2, varscan2
- ACTL8 | c.903C>A p.N301K | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.404); catalogued as COSV100958700; called by muse, mutect2, varscan2
- AGO3 | c.2456T>A p.V819E | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (1); PolyPhen possibly damaging (0.589); catalogued as COSV99868868; called by muse, mutect2, varscan2
- ATP6V0C | c.391A>G p.M131V | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as COSV99565949; called by muse, mutect2, varscan2
- CACNA1C | c.2680C>A p.H894N | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); catalogued as COSV100219756; called by muse, mutect2, varscan2
- CACNG5 | c.553T>A p.S185T | Missense Mutation (SNP) | VAF 39/186 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); catalogued as COSV99400674; called by muse, mutect2, varscan2
- CDC14A | c.789C>G p.F263L | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100325382; called by muse, mutect2, varscan2
- CDH4 | c.343G>T p.A115S | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.084); catalogued as COSV100849198, COSV64675962; called by muse, mutect2, varscan2
- CFAP58 | c.2584G>A p.G862R | Missense Mutation (SNP) | VAF 25/253 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766303918, COSV100866126; called by muse, mutect2, varscan2
- CHD6 | c.975-1G>A p.X325_splice | Splice Site (SNP) | VAF 37/154 reads (24%) | catalogued as COSV100498420; called by muse, mutect2, varscan2
- CMYA5 | c.5466A>T p.K1822N | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.012); catalogued as COSV101484160; called by muse, mutect2, varscan2
- CNBD1 | c.304C>T p.H102Y | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs371689489; called by muse, mutect2, varscan2
- COA6 | c.206T>C p.L69S | Missense Mutation (SNP) | VAF 46/169 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100784590; called by muse, mutect2, varscan2
- CRB1 | c.265C>A p.P89T | Missense Mutation (SNP) | VAF 65/121 reads (54%) | SIFT tolerated (0.23); PolyPhen benign (0.419); catalogued as COSV100959057; called by muse, mutect2, varscan2
- CRISP3 | c.97A>T p.T33S (on ENST00000371159 / NM_001368123.1; = p.T15S on NM_006061.4) | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.037); catalogued as rs751015397, COSV53822132, COSV99539042; called by muse, mutect2, varscan2
- DIPK1A | c.317A>T p.D106V | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0.026); catalogued as COSV100942160; called by muse, mutect2, varscan2
- DTWD1 | c.239C>A p.P80H | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.477); catalogued as COSV99233704; called by muse, mutect2, varscan2
- EIF2AK3 | c.2972T>C p.M991T | Missense Mutation (SNP) | VAF 212/311 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100303883; called by muse, mutect2, varscan2
- ERLEC1 | c.190G>C p.D64H | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as COSV99483093; called by muse, mutect2
- FANCI | c.2387T>C p.M796T | Missense Mutation (SNP) | VAF 54/115 reads (47%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV55531507; called by muse, mutect2, varscan2
- FBL | c.922G>T p.V308L | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.026); catalogued as COSV55683296, COSV99695334; called by muse, mutect2, varscan2
- GLUD1 | c.121C>A p.P41T | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT tolerated (0.14); PolyPhen benign (0.076); catalogued as COSV99518244; called by muse, mutect2
- GPR162 | c.865T>C p.L289= | Splice Region (SNP) | VAF 42/94 reads (45%) | catalogued as COSV99163814; called by muse, mutect2, varscan2
- HNRNPM | c.1043G>T p.G348V | Missense Mutation (SNP) | VAF 45/181 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as COSV100335273; called by muse, mutect2, varscan2
- IL10RA | c.1024C>G p.P342A | Missense Mutation (SNP) | VAF 41/60 reads (68%) | SIFT tolerated (0.12); PolyPhen benign (0.044); catalogued as COSV99923156; called by muse, mutect2, varscan2
- ITGBL1 | c.826T>A p.C276S | Missense Mutation (SNP) | VAF 15/249 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV101095522; called by muse, mutect2
- KCNH1 | c.135C>A p.S45R | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV99659948; called by muse, mutect2
- KRTAP11-1 | c.238C>G p.P80A | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as COSV100190707; called by muse, mutect2, varscan2
- KRTAP19-7 | c.170A>T p.Y57F | Missense Mutation (SNP) | VAF 29/173 reads (17%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.049); catalogued as COSV100603209; called by muse, mutect2, varscan2
- LGALS9 | c.494C>T p.S165F | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs1271902052, COSV100119482; called by muse, mutect2, varscan2
- LHX8 | c.646G>T p.E216* | Nonsense Mutation (SNP) | VAF 24/70 reads (34%) | catalogued as COSV99633945; called by muse, mutect2, varscan2
- LRP1B | c.2657G>C p.C886S | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100796629; called by muse, mutect2, varscan2
- MAMDC4 | c.3578C>T p.A1193V (on ENST00000445819; = p.A1114V on NM_206920.3) | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.411); catalogued as COSV56375737; called by muse, mutect2
- MAP2 | c.1637A>C p.K546T | Missense Mutation (SNP) | VAF 9/176 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.272); catalogued as COSV99560669; called by muse, mutect2
- MAP2 | c.2012G>A p.R671K | Missense Mutation (SNP) | VAF 54/190 reads (28%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.992); catalogued as rs761466743, COSV99560670; called by muse, mutect2, varscan2
- MOGS | c.2363G>A p.R788H | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs199724485; called by muse, mutect2
- MYH15 | c.473C>G p.A158G | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.903); catalogued as COSV99843665; called by muse, mutect2, varscan2
- MYLK4 | c.757A>T p.R253* | Nonsense Mutation (SNP) | VAF 111/405 reads (27%) | catalogued as COSV99193827; called by muse, mutect2, varscan2
- MYO10 | c.5686G>T p.G1896* | Nonsense Mutation (SNP) | VAF 27/192 reads (14%) | catalogued as COSV99945717; called by muse, mutect2, varscan2
- NAV3 | c.4718A>T p.K1573I | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99892646; called by muse, mutect2, varscan2
- NELL1 | c.2354G>T p.G785V | Missense Mutation (SNP) | VAF 32/236 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as COSV100122390; called by muse, mutect2, varscan2
- NEUROG1 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs1470788307, COSV100130816; called by muse, mutect2, varscan2
- NRIP2 | c.691C>A p.Q231K | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.216); catalogued as rs367982122; called by muse, mutect2, varscan2
- NRSN1 | c.346A>C p.K116Q | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as COSV101027312; called by muse, mutect2, varscan2
- NXPH4 | c.641G>A p.G214E | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.179); catalogued as rs1565764595, COSV100197226; called by muse, varscan2
- OR2C3 | c.551T>A p.L184H | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV100825732; called by muse, mutect2, varscan2
- OR2D2 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.113); catalogued as COSV100203871; called by muse, mutect2, varscan2
- OR2T12 | c.104C>G p.T35S | Missense Mutation (SNP) | VAF 52/289 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs749730602, COSV100527846; called by muse, varscan2
- OR4N5 | c.877G>T p.E293* | Nonsense Mutation (SNP) | VAF 58/184 reads (32%) | catalogued as COSV100374130; called by muse, mutect2, varscan2
- PCDHA5 | c.590A>T p.K197I | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100972385; called by muse, varscan2
- PCED1B | c.275A>G p.Y92C | Missense Mutation (SNP) | VAF 132/306 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1318675096, COSV101423666; called by muse, mutect2, varscan2
- PKHD1L1 | c.12176G>T p.W4059L | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as COSV101006423; called by muse, mutect2, varscan2
- PPFIA2 | c.2374T>A p.Y792N | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.085); catalogued as COSV100334222, COSV61024269; called by muse, mutect2, varscan2
- PPP1R13L | c.2434C>T p.R812W | Missense Mutation (SNP) | VAF 15/195 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs763548265, COSV62908353; called by muse, mutect2
- RHBDF2 | c.447G>A p.M149I | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV100489475; called by muse, mutect2
- SEMA3D | c.1897C>A p.H633N | Missense Mutation (SNP) | VAF 75/267 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV99406781, COSV99406925; called by muse, mutect2, varscan2
- SLC11A2 | c.472A>T p.T158S (on ENST00000394904 / NM_001379455.1; = p.T129S on NM_000617.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.386); catalogued as COSV100014861; called by muse, mutect2, varscan2
- SLC39A12 | c.993G>T p.E331D | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.14); catalogued as COSV101070080, COSV101070104; called by muse, mutect2, varscan2
- SPOCK3 | c.1286G>A p.G429D | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV100693268; called by muse, mutect2, varscan2
- TBC1D32 | c.2899G>T p.A967S | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as COSV99250632; called by muse, mutect2, varscan2
- TBCK | c.17A>T p.D6V | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as COSV99912738; called by muse, mutect2, varscan2
- TCERG1 | c.1867G>T p.V623F | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV99695016; called by muse, mutect2, varscan2
- TCF7L1 | c.642G>C p.E214D | Missense Mutation (SNP) | VAF 601/754 reads (80%) | SIFT tolerated (1); PolyPhen possibly damaging (0.492); catalogued as rs1486052719, COSV99964119; called by muse, mutect2, varscan2
- TFR2 | c.1177C>G p.P393A | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV99774588; called by muse, mutect2, varscan2
- TGFBR3 | c.351G>T p.E117D | Missense Mutation (SNP) | VAF 73/165 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV99283240; called by muse, mutect2, varscan2
- THUMPD2 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.047); catalogued as COSV99572254; called by muse, mutect2, varscan2
- TMCO4 | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.67); catalogued as COSV99616965; called by muse, mutect2, varscan2
- TMEM71 | c.577A>T p.I193F (on ENST00000523829 / NM_001382398.1; = p.I174F on NM_144649.3) | Missense Mutation (SNP) | VAF 45/202 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.145); catalogued as COSV100785652; called by muse, mutect2, varscan2
- TMPRSS11A | c.875G>A p.R292H | Missense Mutation (SNP) | VAF 39/199 reads (20%) | SIFT tolerated (0.84); PolyPhen benign (0.249); catalogued as rs139061539; called by muse, mutect2, varscan2
- TRIM49 | c.979A>C p.S327R | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as COSV61670608; called by muse, mutect2
- TRPS1 | c.1717A>T p.S573C (on ENST00000220888 / NM_001330599.2; = p.S586C on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 81/132 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.949); catalogued as COSV99627994; called by muse, mutect2, varscan2
- TRRAP | c.2592C>A p.H864Q | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100722630; called by muse, mutect2, varscan2
- TTN | c.90634C>A p.R30212S (on ENST00000591111; = p.R22788S on NM_003319.4) | Missense Mutation (SNP) | VAF 76/486 reads (16%) | PolyPhen benign (0.345); catalogued as COSV100618981; called by muse, mutect2, varscan2
- USH2A | c.633G>T p.W211C | Missense Mutation (SNP) | VAF 39/167 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100237687; called by muse, mutect2, varscan2
- VCL | c.875-1G>T p.X292_splice | Splice Site (SNP) | VAF 29/161 reads (18%) | catalogued as COSV99281006; called by muse, mutect2, varscan2
- WDR64 | c.1047G>T p.L349F | Missense Mutation (SNP) | VAF 54/168 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63793160; called by muse, mutect2, varscan2
- ZNF257 | c.408T>A p.C136* | Nonsense Mutation (SNP) | VAF 29/113 reads (26%) | catalogued as rs754524624, COSV101448119, COSV71306522; called by muse, mutect2, varscan2
- ZNF32 | c.557A>C p.E186A | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as COSV100986500; called by muse, mutect2
- ZNF804B | c.441G>T p.Q147H | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.956); catalogued as COSV100304523; called by muse, mutect2
- AGPAT2 | c.242_259del p.R81_L86del | In Frame Del (DEL) | VAF 5/45 reads (11%) | called by mutect2, pindel, varscan2
- CNGB1 | c.1047del p.I350Lfs*23 | Frame Shift Del (DEL) | VAF 33/97 reads (34%) | called by mutect2, pindel, varscan2
- LILRA6 | c.685_705del p.T229_L235del | In Frame Del (DEL) | VAF 9/76 reads (12%) | called by mutect2, pindel
- LILRB4 | c.999del p.V334* (on ENST00000391733 / NM_001278428.3; = p.V333* on NM_001278426.3) | Frame Shift Del (DEL) | VAF 37/197 reads (19%) | called by mutect2, pindel, varscan2
- RNF165 | c.802del p.H268Tfs*40 | Frame Shift Del (DEL) | VAF 14/51 reads (27%) | called by mutect2, pindel, varscan2
- ADCY1 | c.2850G>T p.T950= | Silent (SNP) | VAF 89/116 reads (77%) | catalogued as COSV99812366; called by muse, mutect2, varscan2
- ARNTL2 | c.951T>A p.T317= | Silent (SNP) | VAF 27/97 reads (28%) | catalogued as COSV99667886; called by muse, mutect2, varscan2
- ASTN1 | c.408C>T p.P136= | Silent (SNP) | VAF 57/377 reads (15%) | catalogued as COSV99922246; called by muse, mutect2, varscan2
- CCDC122 | c.144G>C p.L48= | Silent (SNP) | VAF 2/8 reads (25%) | catalogued as COSV55709183; called by muse, mutect2
- CCT8L2 | c.43C>T p.L15= | Silent (SNP) | VAF 25/83 reads (30%) | catalogued as rs1201710904, COSV100742865; called by muse, mutect2, varscan2
- CCT8L2 | c.42G>T p.R14= | Silent (SNP) | VAF 25/84 reads (30%) | catalogued as COSV100742867; called by muse, mutect2, varscan2
- CDKN3 | c.465A>G p.L155= | Silent (SNP) | VAF 9/13 reads (69%) | catalogued as COSV99369900; called by muse, mutect2, varscan2
- CHRNB2 | c.945C>T p.S315= | Silent (SNP) | VAF 49/107 reads (46%) | catalogued as rs199549612; called by muse, mutect2, varscan2
- CUL7 | c.2205G>T p.L735= | Silent (SNP) | VAF 75/175 reads (43%) | catalogued as COSV99538839; called by muse, mutect2, varscan2
- DSG4 | c.2607T>C p.P869= | Silent (SNP) | VAF 29/281 reads (10%) | catalogued as COSV57396694; called by muse, mutect2, varscan2
- FAM83D | c.1620C>T p.S540= | Silent (SNP) | VAF 48/181 reads (27%) | catalogued as COSV54159321, COSV99465300; called by muse, mutect2, varscan2
- GLRA4 | c.888C>A p.L296= | Silent (SNP) | VAF 63/123 reads (51%) | catalogued as COSV101009660; called by muse, mutect2, varscan2
- INSC | c.1066C>T p.L356= | Silent (SNP) | VAF 13/93 reads (14%) | catalogued as COSV101089346; called by muse, mutect2, varscan2
- KCNQ5 | c.1368C>A p.G456= | Silent (SNP) | VAF 11/97 reads (11%) | catalogued as COSV100572367; called by muse, mutect2, varscan2
- KIAA0100 | c.6639G>T p.R2213= | Silent (SNP) | VAF 212/390 reads (54%) | catalogued as COSV99972167; called by muse, mutect2, varscan2
- KIF4B | c.858G>T p.V286= | Silent (SNP) | VAF 73/225 reads (32%) | catalogued as COSV101469345; called by muse, mutect2, varscan2
- LRIT1 | c.1221T>A p.L407= | Silent (SNP) | VAF 27/142 reads (19%) | catalogued as COSV100928105; called by muse, mutect2, varscan2
- LRP1 | c.3357C>T p.I1119= | Silent (SNP) | VAF 21/218 reads (10%) | catalogued as COSV54517130, COSV99676324; called by muse, mutect2
- MAPKAPK3 | c.867C>T p.P289= | Silent (SNP) | VAF 48/65 reads (74%) | catalogued as rs1473215021, COSV100781755; called by muse, mutect2, varscan2
- MGA | c.564A>G p.Q188= | Silent (SNP) | VAF 129/341 reads (38%) | catalogued as COSV99580489; called by muse, mutect2, varscan2
- MTAP | c.558C>T p.F186= | Silent (SNP) | VAF 22/115 reads (19%) | catalogued as COSV101205476; called by muse, mutect2, varscan2
- MUC5B | c.14502C>G p.S4834= | Silent (SNP) | VAF 24/161 reads (15%) | catalogued as COSV101500486; called by muse, mutect2, varscan2
- MYH4 | c.1572C>T p.I524= | Silent (SNP) | VAF 61/219 reads (28%) | catalogued as rs1212405204, COSV55115904; called by muse, mutect2, varscan2
- NFATC2 | c.1563T>G p.L521= | Silent (SNP) | VAF 28/117 reads (24%) | catalogued as COSV101044279; called by muse, mutect2, varscan2
- NINL | c.3141C>T p.T1047= | Silent (SNP) | VAF 41/210 reads (20%) | catalogued as rs918533345, COSV99625628; called by muse, mutect2, varscan2
- OR2L13 | c.741G>A p.V247= | Silent (SNP) | VAF 31/209 reads (15%) | catalogued as COSV63549877; called by muse, mutect2, varscan2
- PEX11B | c.393C>G p.L131= | Silent (SNP) | VAF 129/266 reads (48%) | catalogued as COSV100994955, COSV65197444; called by muse, mutect2, varscan2
- PIGS | c.798C>G p.G266= | Silent (SNP) | VAF 51/110 reads (46%) | catalogued as COSV99257088; called by muse, mutect2, varscan2
- PLCB2 | c.1827C>A p.R609= | Silent (SNP) | VAF 55/153 reads (36%) | catalogued as COSV53038983; called by muse, mutect2, varscan2
- PRAMEF14 | c.540G>C p.L180= | Silent (SNP) | VAF 193/635 reads (30%) | called by muse, mutect2, varscan2
- PREX1 | c.2883G>T p.P961= | Silent (SNP) | VAF 20/120 reads (17%) | catalogued as COSV64255201; called by muse, mutect2, varscan2
- PRIMA1 | c.384T>C p.N128= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV60265462; called by muse, mutect2, varscan2
- SART3 | c.2625T>G p.A875= (on ENST00000228284; = p.A857= on NM_014706.4) | Silent (SNP) | VAF 29/143 reads (20%) | catalogued as rs746063807, COSV99934191; called by muse, mutect2, varscan2
- SERPINA3 | c.630C>T p.Y210= | Silent (SNP) | VAF 18/161 reads (11%) | catalogued as COSV101261742; called by muse, mutect2, varscan2
- SOBP | c.1602G>A p.P534= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as rs1375927729, COSV100433258; called by muse, mutect2, varscan2
- SYT17 | c.1101T>C p.H367= | Silent (SNP) | VAF 39/116 reads (34%) | catalogued as rs373690785; called by muse, mutect2, varscan2
- TMEM200A | c.1204C>A p.R402= | Silent (SNP) | VAF 38/96 reads (40%) | catalogued as COSV51654837, COSV51657942; called by muse, mutect2, varscan2
- TNN | c.2814T>G p.T938= | Silent (SNP) | VAF 39/130 reads (30%) | catalogued as COSV99512286; called by muse, mutect2, varscan2
- ZNF10 | c.912G>T p.R304= | Silent (SNP) | VAF 44/142 reads (31%) | catalogued as COSV99940040; called by muse, mutect2, varscan2
- ZNF599 | c.813G>A p.T271= | Silent (SNP) | VAF 78/227 reads (34%) | catalogued as rs201514857; called by muse, mutect2, varscan2
- CPLANE1 | c.*5829A>T | 3'UTR (SNP) | VAF 32/245 reads (13%) | catalogued as COSV99950950; called by muse, mutect2, varscan2
- FLCN | c.871+51G>T | Intron (SNP) | VAF 39/109 reads (36%) | catalogued as COSV99550520; called by muse, mutect2, varscan2
- KRT18P55 | n.855G>T | RNA (SNP) | VAF 27/199 reads (14%) | called by muse, mutect2, varscan2
- SNTG1 | chr8:50792830 C>T | 3'Flank (SNP) | VAF 50/200 reads (25%) | catalogued as COSV99384457; called by muse, mutect2, varscan2
- SSX9P | n.443C>G | RNA (SNP) | VAF 67/361 reads (19%) | called by muse, mutect2, varscan2
